Somatic mutation profile of cancer-model specimen HCM-BROD-0130-C25-85M (3D Organoid, passage 5; aliquot HCM-BROD-0130-C25-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0130-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.6 years (21,030 days).
Specimen HCM-BROD-0130-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e6f2971-94ac-4ce6-bd02-0e3a8790b4b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0130-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0130-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/809c9489-3991-4acd-8f91-09441f013df8

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, Splice Site 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPR2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777596, CM1312322, COSV61041918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 417/418 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CDC42BPG | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 196/664 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs775596454; called by muse, mutect2, varscan2
- CUL9 | c.5861C>T p.P1954L | Missense Mutation (SNP) | VAF 195/420 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1316056101; called by muse, mutect2, varscan2
- FOXJ1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 178/530 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs1318544381; called by muse, mutect2, varscan2
- GPIHBP1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 271/1071 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746247359, COSV58209384; called by muse, mutect2, varscan2
- ITGA9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374110267; called by muse, mutect2, varscan2
- KLHL4 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 158/218 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909705; called by muse, mutect2, varscan2
- KMT2C | c.4174C>T p.Q1392* | Nonsense Mutation (SNP) | VAF 110/267 reads (41%) | catalogued as COSV51426883; called by muse, mutect2, varscan2
- OTUD7A | c.943G>A p.V315I (on ENST00000307050 / NM_001382637.1; = p.V308I on NM_130901.3) | Missense Mutation (SNP) | VAF 160/336 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61038042; called by muse, mutect2, varscan2
- PCDHB2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 304/838 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs782682660, COSV99164149, COSV99166535; called by muse, mutect2, varscan2
- SAMD9 | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 149/287 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1188656521; called by muse, mutect2, varscan2
- SCO2 | c.39G>C p.R13S | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV99329475; called by muse, mutect2
- SLC23A3 | c.1553G>A p.R518Q (on ENST00000409878 / NM_001144889.2; = p.R401Q on NM_144712.5) | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373144689, COSV104404080; called by muse, mutect2, varscan2
- SLC38A4 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1218992058, COSV56965260; called by muse, mutect2, varscan2
- TMEM132A | c.2992C>T p.R998C (on ENST00000453848 / NM_178031.3; = p.R999C on NM_017870.4) | Missense Mutation (SNP) | VAF 276/548 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368115669; called by muse, mutect2, varscan2
- TPBG | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs773244685, COSV63882308; called by muse, mutect2
- WIZ | c.2569A>T p.I857F (on ENST00000673675 / NM_001371589.1; = p.I120F on NM_021241.3) | Missense Mutation (SNP) | VAF 549/561 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99653020; called by muse, mutect2, varscan2
- ZCCHC12 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746217095, COSV59573098; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 146/314 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- AGBL2 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 139/277 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP8L | c.1091A>C p.K364T | Missense Mutation (SNP) | VAF 13/413 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2
- ANKLE1 | c.799T>A p.W267R (on ENST00000394458; = p.W213R on NM_152363.6) | Missense Mutation (SNP) | VAF 15/468 reads (3%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.476); called by muse, mutect2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 67/222 reads (30%) | called by mutect2, pindel, varscan2
- C3orf52 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 220/438 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCDC114 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 196/202 reads (97%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EML6 | c.2657A>G p.D886G | Missense Mutation (SNP) | VAF 175/327 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- EXOC3L4 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 296/712 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR146 | c.370A>C p.S124R | Missense Mutation (SNP) | VAF 222/486 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HERC2 | c.8305C>G p.R2769G | Missense Mutation (SNP) | VAF 231/522 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LPCAT4 | c.1239T>G p.F413L | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- LRP1B | c.2869G>T p.D957Y | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OSBPL7 | c.133_135dup p.V45dup | In Frame Ins (INS) | VAF 145/631 reads (23%) | called by mutect2, pindel, varscan2
- PDE3A | c.1358T>C p.L453S | Missense Mutation (SNP) | VAF 190/400 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RAB11FIP2 | c.363A>T p.R121S | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- SUPT6H | c.3643C>A p.H1215N | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D3F | c.73-1G>A p.X25_splice | Splice Site (SNP) | VAF 151/580 reads (26%) | called by muse, mutect2, varscan2
- TPO | c.2506A>T p.R836* | Nonsense Mutation (SNP) | VAF 161/320 reads (50%) | called by muse, mutect2, varscan2
- TTF2 | c.2808_2809dup p.L937Pfs*7 | Frame Shift Ins (INS) | VAF 68/207 reads (33%) | called by pindel, varscan2
- TUBGCP6 | c.3655T>C p.S1219P | Missense Mutation (SNP) | VAF 212/390 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF407 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2
- ABCA4 | c.3000A>G p.A1000= | Silent (SNP) | VAF 14/418 reads (3%) | called by muse, mutect2
- ADARB2 | c.546G>C p.A182= | Silent (SNP) | VAF 233/658 reads (35%) | catalogued as COSV67219710; called by muse, mutect2, varscan2
- DISP2 | c.492G>C p.L164= | Silent (SNP) | VAF 124/277 reads (45%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1842G>A p.S614= | Silent (SNP) | VAF 91/238 reads (38%) | catalogued as rs773332244; called by muse, mutect2, varscan2
- FMN2 | c.924G>A p.P308= | Silent (SNP) | VAF 32/950 reads (3%) | called by muse, mutect2
- ICAM2 | c.684C>T p.V228= | Silent (SNP) | VAF 148/484 reads (31%) | called by muse, mutect2, varscan2
- IMPG2 | c.2094G>A p.A698= | Silent (SNP) | VAF 178/351 reads (51%) | catalogued as rs774027495; called by muse, mutect2, varscan2
- MADD | c.2259A>G p.R753= | Silent (SNP) | VAF 149/474 reads (31%) | called by muse, mutect2, varscan2
- PKD1L1 | c.3945T>C p.S1315= | Silent (SNP) | VAF 156/299 reads (52%) | called by muse, mutect2, varscan2
- SMC1B | c.3087T>G p.T1029= | Silent (SNP) | VAF 137/280 reads (49%) | called by muse, mutect2, varscan2
- ZNF407 | c.2520G>A p.K840= | Silent (SNP) | VAF 11/389 reads (3%) | called by muse, mutect2
- ZNF564 | c.1344T>C p.P448= | Silent (SNP) | VAF 310/318 reads (97%) | called by muse, mutect2, varscan2
- ZNF783 | c.405G>A p.K135= | Silent (SNP) | VAF 152/349 reads (44%) | catalogued as rs761353217, COSV65184974; called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 30/263 reads (11%) | catalogued as rs73150876; called by muse, mutect2
- CD109 | chr6:73696187 G>A | 5'Flank (SNP) | VAF 178/351 reads (51%) | called by muse, mutect2, varscan2
- HMBS | c.826-38C>A | Intron (SNP) | VAF 109/306 reads (36%) | called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 16/150 reads (11%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
